Somatic mutation profile of tumor specimen HCM-CSHL-0729-C18-01A (aliquot HCM-CSHL-0729-C18-01A-11D-A82I-36) from HCMI case HCM-CSHL-0729-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GB; Age at diagnosis: 60.0 years (21,919 days).
Specimen HCM-CSHL-0729-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d350eed-92a6-40f6-ad4d-aadbd79ab3de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0729-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0729-C18-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63362632-a822-42ea-bba3-c24d044bac39

The open-access MAF lists 1,449 somatic variants for this specimen: 1,177 protein-altering or splice-affecting, 216 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 940, Silent 216, Nonsense Mutation 201, Intron 40, Frame Shift Ins 17, Splice Region 5, RNA 5, Nonstop Mutation 5, 3'UTR 4, Frame Shift Del 3, Translation Start Site 3, Splice Site 3.

Variants (750 of 1,449; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 28/214 reads (13%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CTLA4 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 97/434 reads (22%) | catalogued as rs886041906, COSV55591750, COSV99865404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 50/303 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD18 | c.909G>T p.M303I (on ENST00000398965 / NM_001039717.2; = p.M210I on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV66292975; called by muse, mutect2, varscan2
- ABLIM3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs757248481; called by muse, mutect2
- ACAA2 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99551704; called by muse, mutect2, varscan2
- ACVR1B | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 21/555 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57778801; called by muse, mutect2
- ACVR1C | c.996A>T p.K332N | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54645046; called by muse, mutect2, varscan2
- ADAM10 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 24/434 reads (6%) | catalogued as COSV53052589; called by muse, mutect2
- ADAM20 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 80/366 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV56456746; called by muse, mutect2, varscan2
- ADAM22 | c.1563C>A p.S521R | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55974834; called by muse, mutect2, varscan2
- ADGRE3 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 46/170 reads (27%) | catalogued as COSV53734782; called by muse, mutect2, varscan2
- ADGRV1 | c.8461G>T p.E2821* | Nonsense Mutation (SNP) | VAF 68/325 reads (21%) | catalogued as COSV67994316; called by muse, mutect2, varscan2
- ADRA1B | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60704291; called by muse, mutect2, varscan2
- AGTR1 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV62558999; called by muse, mutect2, varscan2
- AKAP9 | c.6221A>G p.Q2074R (on ENST00000359028; = p.Q2042R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs762427337; called by muse, mutect2, varscan2
- AMER1 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 84/775 reads (11%) | catalogued as COSV57663510; called by muse, mutect2, varscan2
- AMER1 | c.971C>A p.S324* | Nonsense Mutation (SNP) | VAF 139/716 reads (19%) | catalogued as COSV57665666; called by muse, mutect2, varscan2
- ANK1 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 71/278 reads (26%) | catalogued as COSV55874984, COSV55880954; called by muse, mutect2, varscan2
- ANK2 | c.6756G>T p.K2252N | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52185348; called by muse, mutect2, varscan2
- ANK3 | c.4038G>T p.E1346D (on ENST00000280772 / NM_001320874.2; = p.E480D on NM_001149.3) | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1211661757; called by muse, mutect2
- ANO4 | c.311G>T p.R104I (on ENST00000392977 / NM_001286615.2; = p.R69I on NM_178826.4) | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54591769; called by muse, mutect2, varscan2
- AP002512.3 | c.581C>A p.T194N | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV54405568; called by muse, mutect2, varscan2
- AP002748.5 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 42/203 reads (21%) | catalogued as COSV59148777; called by muse, mutect2, varscan2
- APBA1 | c.1435A>C p.K479Q | Missense Mutation (SNP) | VAF 75/644 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55223830; called by muse, mutect2, varscan2
- APC | c.2937G>T p.M979I | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV57332823; called by muse, mutect2, varscan2
- APOB | c.13159G>T p.E4387* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV51922117; called by muse, mutect2, varscan2
- APOB | c.12835G>T p.E4279* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as COSV51928518; called by muse, mutect2, varscan2
- ARAP2 | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | catalogued as COSV58283400; called by muse, mutect2, varscan2
- AREG | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV99144390; called by muse, mutect2, varscan2
- ARFGEF2 | c.3977T>G p.V1326G | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1263411905; called by muse, mutect2, varscan2
- ARHGAP21 | c.1925C>A p.S642* | Nonsense Mutation (SNP) | VAF 24/386 reads (6%) | catalogued as COSV57610649; called by muse, mutect2
- ARID2 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV57607926; called by muse, mutect2
- ART3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.232); catalogued as rs947944389; called by muse, mutect2, varscan2
- ASIC5 | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV72232857; called by muse, mutect2, varscan2
- ASMT | c.987C>A p.F329L (on ENST00000381229; = p.F357L on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/778 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67110398; called by muse, mutect2
- ASXL3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 75/392 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as rs749484741, COSV52457610; called by muse, mutect2, varscan2
- ATF7-NPFF | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 114/489 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs768475017; called by muse, mutect2, varscan2
- ATF7IP2 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV61095647; called by muse, mutect2
- ATP6V1FNB | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 100/489 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs1422813927; called by muse, mutect2, varscan2
- ATXN7L1 | c.357G>A p.E119= | Splice Region (SNP) | VAF 16/214 reads (7%) | catalogued as COSV69306000; called by muse, mutect2
- B2M | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 68/378 reads (18%) | catalogued as COSV62563605; called by muse, varscan2
- B2M | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 53/372 reads (14%) | catalogued as COSV62563917; called by muse, varscan2
- BCAP31 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 78/322 reads (24%) | catalogued as COSV61452492; called by muse, mutect2, varscan2
- BCL2L11 | c.574C>T p.R192C (on ENST00000393256 / NM_138621.5; = p.R132C on NM_006538.5) | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758817904, COSV58027602; called by muse, mutect2, varscan2
- BCR | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 80/478 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100005938; called by muse, mutect2, varscan2
- BORCS8 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1363024959; called by muse, mutect2, varscan2
- BRAF | c.2330G>A p.G777D (on ENST00000288602 / NM_001374244.1; = p.G737D on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/470 reads (20%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as rs778872326; called by muse, mutect2, varscan2
- BRCA1 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs147519994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTK | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV58118418; called by mutect2, varscan2
- C2orf42 | c.51G>T p.L17F | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52451947; called by muse, mutect2, varscan2
- C7orf31 | c.1387C>A p.H463N | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.023); catalogued as COSV52219915; called by mutect2, varscan2
- C8G | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1163095078; called by muse, mutect2, varscan2
- CA1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 58/342 reads (17%) | catalogued as rs373804439, COSV56277599; called by muse, mutect2, varscan2
- CALD1 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 49/609 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs148922576; called by muse, mutect2
- CAMK1G | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 82/400 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as rs144255822; called by muse, mutect2, varscan2
- CASD1 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 28/260 reads (11%) | catalogued as COSV51970648; called by muse, mutect2
- CCDC125 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs3197129; called by muse, mutect2, varscan2
- CCDC158 | c.2912C>A p.S971* | Nonsense Mutation (SNP) | VAF 24/374 reads (6%) | catalogued as COSV66357071; called by muse, mutect2
- CCDC168 | c.11448G>T p.K3816N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1480172220, COSV59423601; called by muse, mutect2, varscan2
- CCDC168 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 53/253 reads (21%) | catalogued as COSV70555535; called by muse, mutect2, varscan2
- CCDC39 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs749525425, COSV56477817, COSV56484645; called by muse, mutect2, varscan2
- CCNYL1 | c.853A>C p.N285H (on ENST00000295414 / NM_001330218.2; = p.N215H on NM_152523.2) | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV54941555; called by muse, mutect2, varscan2
- CCT8L2 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 102/514 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1166565426; called by muse, mutect2, varscan2
- CD1D | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV63808373; called by muse, mutect2
- CD209 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 184/907 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV99214213; called by muse, mutect2, varscan2
- CD300LG | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 88/377 reads (23%) | catalogued as COSV53225399, COSV53225599; called by muse, mutect2, varscan2
- CDC27 | c.2274G>T p.M758I | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV50677156; called by muse, mutect2, varscan2
- CDH8 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV100181039; called by muse, mutect2, varscan2
- CDK8 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101037399, COSV67419346; called by muse, mutect2, varscan2
- CENPF | c.444T>G p.I148M | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV65279976; called by muse, mutect2, varscan2
- CENPJ | c.3730G>T p.E1244* | Nonsense Mutation (SNP) | VAF 32/149 reads (21%) | catalogued as COSV55045835; called by muse, mutect2, varscan2
- CEP72 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53791565; called by muse, mutect2, varscan2
- CFAP157 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 23/452 reads (5%) | catalogued as rs1474695898; called by muse, mutect2
- CFAP54 | c.8558dup p.L2854Pfs*2 | Frame Shift Ins (INS) | VAF 40/199 reads (20%) | catalogued as rs1347360579; called by mutect2, pindel, varscan2
- CHAF1A | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 128/563 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.058); catalogued as COSV56675073; called by muse, mutect2, varscan2
- CHD8 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 85/402 reads (21%) | catalogued as rs1555318703; called by muse, mutect2, varscan2
- CHRNA9 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs887313309; called by muse, mutect2
- CHST15 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 92/458 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs202236206, COSV60562996; called by muse, mutect2, varscan2
- CLASP2 | c.2488C>A p.P830T | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.176); catalogued as rs755187415; called by muse, mutect2, varscan2
- CLDN20 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 83/389 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs1391123602, COSV65697255, COSV65697705; called by muse, mutect2, varscan2
- CLEC14A | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 85/385 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60564115; called by muse, mutect2, varscan2
- CLHC1 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs1469147865; called by muse, mutect2
- CNTNAP4 | c.2914G>T p.G972* | Nonsense Mutation (SNP) | VAF 64/389 reads (16%) | catalogued as COSV56681470; called by muse, mutect2, varscan2
- COL12A1 | c.2425G>T p.A809S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as COSV59389646; called by muse, mutect2, varscan2
- COL15A1 | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs755450632; called by muse, varscan2
- COL6A5 | c.1465G>T p.D489Y | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV55194974; called by muse, mutect2, varscan2
- COL6A5 | c.2251C>A p.L751I | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs1371007654, COSV55199121; called by muse, mutect2, varscan2
- COL6A5 | c.6820C>A p.P2274T (on ENST00000312481; = p.P2270T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV99594306; called by mutect2, varscan2
- CPS1 | c.3733C>A p.L1245I | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.583); catalogued as COSV51817311; called by muse, mutect2, varscan2
- CPT2 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs938668766; called by muse, mutect2
- CRELD2 | c.898dup p.T300Nfs*22 | Frame Shift Ins (INS) | VAF 83/437 reads (19%) | catalogued as rs1215550833; called by mutect2, pindel, varscan2
- CRISPLD1 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 109/498 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV100081988; called by muse, mutect2, varscan2
- CRTAC1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 173/752 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as rs199517598; called by muse, mutect2, varscan2
- CSNK2A1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53937777, COSV99424750; called by muse, mutect2, varscan2
- CTNNA3 | c.2211G>T p.M737I | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs192848934; called by muse, mutect2, varscan2
- CYFIP2 | c.2032G>T p.E678* (on ENST00000616178 / NM_001291722.2; = p.E653* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 59/381 reads (15%) | catalogued as COSV100556449; called by muse, mutect2, varscan2
- CYP11B1 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 143/597 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV52827157, COSV99455544; called by muse, mutect2, varscan2
- CYP4A22 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 97/404 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs772583047, COSV53739901; called by muse, mutect2, varscan2
- DAB1 | c.1500G>T p.L500F (on ENST00000371231; = p.L467F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/465 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV64696727; called by muse, mutect2, varscan2
- DAZAP2 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV66313265; called by muse, mutect2, varscan2
- DCAF4L2 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 86/425 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV60477762, COSV60480991; called by muse, mutect2, varscan2
- DCLRE1C | c.1294A>C p.T432P (on ENST00000378278 / NM_001350965.2; = p.T317P on NM_022487.4) | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1163287742; called by muse, mutect2
- DEPDC4 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV54552923; called by muse, mutect2, varscan2
- DIPK1A | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64792667; called by muse, mutect2, varscan2
- DISP1 | c.4375G>T p.E1459* | Nonsense Mutation (SNP) | VAF 47/325 reads (14%) | catalogued as COSV52654944; called by muse, mutect2, varscan2
- DMRT2 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 137/516 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs1438193635; called by muse, mutect2, varscan2
- DNAH8 | c.8083G>T p.V2695L | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59486310; called by mutect2, varscan2
- DNAH8 | c.12986G>T p.R4329I | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221140553, COSV59435605, COSV59460628; called by muse, mutect2, varscan2
- DNTTIP2 | c.2021G>T p.R674I | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63284373; called by muse, mutect2
- DROSHA | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 77/429 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60772166; called by muse, mutect2, varscan2
- DSP | c.4093C>A p.Q1365K | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101131742; called by muse, mutect2
- DYNC1I1 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61472410; called by muse, mutect2, varscan2
- DYNC2H1 | c.1173T>G p.I391M | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as rs1286571022; called by muse, mutect2, varscan2
- DZIP1L | c.1643C>A p.T548N | Missense Mutation (SNP) | VAF 36/533 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs201114444; called by muse, mutect2
- EBF3 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV62475179; called by muse, mutect2, varscan2
- EDDM3B | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 47/268 reads (18%) | catalogued as COSV58747030; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1959C>A p.F653L | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100668326, COSV62571229; called by muse, mutect2, varscan2
- EFCAB6 | c.1007G>T p.R336I | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs1450251858, COSV53073426; called by muse, mutect2, varscan2
- EIF4EBP3 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 145/642 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.245); catalogued as rs781551674; called by muse, mutect2, varscan2
- ELOA2 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 92/536 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1218680153; called by muse, varscan2
- EPB41L4A | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99813287; called by muse, mutect2, varscan2
- EPB41L4B | c.702T>A p.N234K | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.089); catalogued as rs944891415; called by muse, mutect2, varscan2
- EPHA3 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 79/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100341729; called by muse, mutect2, varscan2
- EPHA6 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 58/286 reads (20%) | catalogued as COSV67571138, COSV67578619; called by mutect2, varscan2
- EPS8 | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 84/484 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1336240695; called by muse, mutect2, varscan2
- ERBB3 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 101/564 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV57248919; called by muse, mutect2, varscan2
- ERICH3 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 68/296 reads (23%) | catalogued as rs145428486; called by muse, mutect2, varscan2
- ESAM | c.548T>A p.V183D | Missense Mutation (SNP) | VAF 85/618 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs779588823; called by muse, mutect2, varscan2
- EXPH5 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as COSV56204775; called by muse, mutect2, varscan2
- F8 | c.5799G>T p.E1933D | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV64269296; called by muse, mutect2, varscan2
- FADS6 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 77/374 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59603038; called by muse, mutect2, varscan2
- FAM160A2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 142/697 reads (20%) | catalogued as COSV56412579; called by muse, mutect2, varscan2
- FAM214A | c.2647G>T p.E883* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV55925794; called by mutect2, varscan2
- FBXO46 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 173/846 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs770645321; called by muse, mutect2, varscan2
- FBXW10 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 100/345 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs766712663, COSV57059522; called by muse, varscan2
- FCER1G | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 54/342 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV57156355; called by muse, mutect2
- FCRL2 | c.1036G>C p.A346P | Missense Mutation (SNP) | VAF 114/495 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1405874429, COSV63833904; called by muse, mutect2, varscan2
- FER1L6 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV101205444; called by muse, mutect2, varscan2
- FIGNL1 | c.1579C>A p.Q527K | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63553167; called by muse, mutect2, varscan2
- FLNC | c.3511G>A p.G1171S | Missense Mutation (SNP) | VAF 166/807 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs769490872, COSV57953088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FN1 | c.2943C>A p.S981R | Missense Mutation (SNP) | VAF 66/377 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.143); catalogued as COSV60556085; called by muse, mutect2, varscan2
- FNBP1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV63090766; called by mutect2, varscan2
- FOLR2 | c.622T>G p.F208V | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53352180, COSV53352471; called by muse, mutect2
- FREM1 | c.6033G>T p.K2011N | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV66530567; called by muse, mutect2
- FRS3 | c.879dup p.L294Afs*30 | Frame Shift Ins (INS) | VAF 84/882 reads (10%) | catalogued as rs768098936; called by mutect2, pindel
- FSHR | c.1766C>A p.S589Y | Missense Mutation (SNP) | VAF 21/595 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100436666; called by muse, mutect2
- FSIP2 | c.18558T>G p.F6186L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as rs1309357649; called by muse, mutect2, varscan2
- GABRG1 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV54959931; called by muse, mutect2, varscan2
- GALNT9 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 110/564 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs781085284, COSV61097448; called by muse, mutect2, varscan2
- GANC | c.1860C>A p.F620L | Missense Mutation (SNP) | VAF 72/330 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV58810893; called by muse, mutect2
- GAP43 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 37/212 reads (17%) | catalogued as COSV59344455; called by muse, mutect2, varscan2
- GGA3 | c.1976C>T p.P659L (on ENST00000537686 / NM_138619.4; = p.P626L on NM_014001.5) | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759820278; called by muse, mutect2, varscan2
- GIPC1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 23/655 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.885); catalogued as rs1404951331, COSV61775036; called by muse, mutect2
- GLB1 | c.795C>A p.I265= | Splice Region (SNP) | VAF 20/320 reads (6%) | catalogued as rs1339270920; called by muse, mutect2
- GLP2R | c.1257C>A p.F419L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as COSV52324428; called by mutect2, varscan2
- GLRB | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765701013; called by muse, mutect2, varscan2
- GPATCH8 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 90/514 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs751449158, COSV59194287; called by muse, mutect2, varscan2
- GRAMD1B | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 125/638 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV59211920; called by muse, mutect2, varscan2
- GREB1 | c.1717C>A p.L573I | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52184393; called by muse, mutect2, varscan2
- GRIA3 | c.2220G>T p.M740I | Missense Mutation (SNP) | VAF 29/377 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV52054320; called by muse, mutect2
- GTF2B | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 62/292 reads (21%) | catalogued as COSV65136884; called by muse, mutect2, varscan2
- HDC | c.1890C>A p.F630L | Missense Mutation (SNP) | VAF 60/497 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs1471890215; called by mutect2, varscan2
- HDC | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51081508; called by muse, mutect2, varscan2
- HELQ | c.1788G>T p.M596I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1191301199, COSV55028472; called by muse, mutect2, varscan2
- HMGCLL1 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 27/185 reads (15%) | catalogued as COSV51451966; called by muse, mutect2, varscan2
- HNRNPF | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 131/536 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV61561688; called by muse, mutect2, varscan2
- HP1BP3 | c.394dup p.T132Nfs*36 | Frame Shift Ins (INS) | VAF 74/314 reads (24%) | catalogued as rs1248069646; called by mutect2, varscan2
- HRH3 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 51/744 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754210266; called by muse, mutect2
- HTR3D | c.369C>A p.F123L (on ENST00000382489 / NM_001163646.2; = p.F62L on NM_001145143.1) | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV61913191; called by muse, mutect2, varscan2
- HTRA1 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 105/472 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1422468280; called by muse, mutect2, varscan2
- IDI1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777622677; called by muse, mutect2, varscan2
- IFIT5 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100877969; called by muse, mutect2
- IFT57 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs774931041, COSV52711861; called by muse, mutect2, varscan2
- IGSF10 | c.5866G>T p.G1956W | Missense Mutation (SNP) | VAF 89/430 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56782471; called by muse, mutect2, varscan2
- IL18RAP | c.87dup p.L30Tfs*10 | Frame Shift Ins (INS) | VAF 12/73 reads (16%) | catalogued as rs756319084; called by mutect2, pindel*, varscan2
- IL7R | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV57411421; called by muse, mutect2, varscan2
- INTU | c.1664G>T p.R555I | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs774690451; called by muse, mutect2, varscan2
- ITGB2 | c.1850G>A p.R617H (on ENST00000302347; = p.R593H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/726 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs749255547, COSV56608418; called by muse, varscan2
- KALRN | c.7891G>T p.D2631Y (on ENST00000360013 / NM_001024660.4; = p.D934Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/497 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52258370; called by muse, mutect2
- KBTBD2 | c.1503T>G p.I501M | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV100406565; called by muse, mutect2, varscan2
- KCNH7 | c.1322G>T p.R441I | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1251173767; called by muse, mutect2, varscan2
- KCNH8 | c.2082A>C p.S694= | Splice Region (SNP) | VAF 66/256 reads (26%) | catalogued as rs1301281983; called by muse, mutect2, varscan2
- KCNQ3 | c.1600T>A p.F534I | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66467174; called by mutect2, varscan2
- KDM4E | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 97/449 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.234); catalogued as rs1390764735; called by muse, mutect2, varscan2
- KIAA1109 | c.12344G>T p.G4115V | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52678318; called by muse, mutect2, varscan2
- KIAA1671 | c.4655C>A p.A1552D | Missense Mutation (SNP) | VAF 90/313 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs773445204; called by muse, mutect2, varscan2
- KIF26B | c.3491C>A p.S1164Y | Missense Mutation (SNP) | VAF 158/662 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as COSV63649141; called by mutect2, varscan2
- KLF10 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53436001; called by muse, mutect2
- KNL1 | c.5419G>T p.E1807* (on ENST00000346991 / NM_170589.5; = p.E1781* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV61152792; called by muse, mutect2, varscan2
- KRT25 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 12/252 reads (5%) | catalogued as rs1188079561, COSV56445232; called by muse, mutect2
- KRT27 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 34/561 reads (6%) | catalogued as COSV100053297; called by muse, mutect2
- KRT6B | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs771623502, COSV52885484; called by muse, mutect2, varscan2
- KRTAP19-4 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100478592; called by muse, mutect2, varscan2
- LAMP5 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 84/476 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs777491312, COSV55718164; called by muse, mutect2, varscan2
- LATS1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV53590373, COSV53599929; called by muse, mutect2, varscan2
- LCT | c.2110G>T p.D704Y | Missense Mutation (SNP) | VAF 38/661 reads (6%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.724); catalogued as COSV51552627; called by muse, mutect2
- LMNTD1 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as COSV51450721, COSV51450758; called by muse, mutect2, varscan2
- LONRF2 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 43/169 reads (25%) | catalogued as COSV66539347; called by muse, mutect2, varscan2
- LRP1B | c.12691G>T p.E4231* | Nonsense Mutation (SNP) | VAF 59/253 reads (23%) | catalogued as rs1419834168; called by muse, mutect2, varscan2
- LRRC7 | c.1845G>T p.K615N (on ENST00000651989 / NM_001370785.2; = p.K582N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs267598705; called by muse, mutect2
- LSM14A | c.1288A>T p.T430S | Missense Mutation (SNP) | VAF 53/798 reads (7%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV70885770; called by muse, mutect2
- LVRN | c.2725T>G p.L909V | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.228); catalogued as rs1320407013; called by muse, mutect2, varscan2
- MACF1 | c.2693C>A p.S898Y | Missense Mutation (SNP) | VAF 88/396 reads (22%) | catalogued as rs774515220, COSV58380576; called by muse, mutect2, varscan2
- MAGEC2 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 128/639 reads (20%) | catalogued as COSV55998321, COSV56002040; called by muse, mutect2, varscan2
- MAGEC3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 132/690 reads (19%) | catalogued as COSV53580537; called by muse, mutect2, varscan2
- MAGEC3 | c.1572C>A p.F524L | Missense Mutation (SNP) | VAF 106/478 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs780880692, COSV100025945, COSV53577680; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by mutect2, varscan2
- MAML2 | c.858G>T p.E286D | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs1468626617, COSV73264793; called by muse, mutect2
- MAP7D3 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 35/501 reads (7%) | catalogued as COSV100286458; called by muse, mutect2
- MARK1 | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65070121; called by muse, mutect2, varscan2
- MCM6 | c.1779C>A p.F593L | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV51469669; called by muse, mutect2, varscan2
- MEGF6 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 111/527 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs764681187, COSV99619990; called by muse, mutect2, varscan2
- MEPE | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as rs746510246; called by mutect2, varscan2
- MKLN1 | c.1792C>A p.H598N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs777468548, COSV61760448, COSV61761541; called by muse, mutect2, varscan2
- MMP13 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs189974040; called by muse, mutect2, varscan2
- MTF2 | c.8A>T p.D3V | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV104427396; called by muse, mutect2, varscan2
- MTREX | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as COSV100043876; called by muse, mutect2, varscan2
- MUC16 | c.24541G>T p.E8181* | Nonsense Mutation (SNP) | VAF 79/451 reads (18%) | catalogued as COSV101201359; called by muse, mutect2, varscan2
- MUC16 | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 98/422 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs761616274, COSV67457388; called by muse, mutect2, varscan2
- MYH3 | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 117/510 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs770477653, COSV56862050; called by muse, mutect2, varscan2
- MYH9 | c.2033A>G p.K678R | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1220725450; called by muse, mutect2, varscan2
- MYLK | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 50/482 reads (10%) | catalogued as COSV60620014; called by muse, mutect2, varscan2
- MYOC | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/543 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV50676446; called by muse, mutect2
- MYPN | c.3711G>T p.K1237N | Missense Mutation (SNP) | VAF 115/560 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.816); catalogued as COSV62739404; called by muse, mutect2, varscan2
- MYRIP | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56861662; called by muse, mutect2
- NBEA | c.2211G>T p.M737I | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV59773954, COSV59797102; called by muse, mutect2, varscan2
- NBEAL1 | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs1279943714; called by muse, varscan2
- NBEAL1 | c.2592T>G p.I864M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1377187978; called by muse, mutect2, varscan2
- NCKAP5 | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 64/275 reads (23%) | catalogued as rs1239979798, COSV58444568; called by muse, mutect2, varscan2
- NDST4 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 18/143 reads (13%) | catalogued as COSV52134737; called by muse, mutect2, varscan2
- NET1 | c.490A>C p.M164L (on ENST00000355029 / NM_001047160.3; = p.M110L on NM_005863.5) | Missense Mutation (SNP) | VAF 77/424 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs572860536; called by muse, mutect2, varscan2
- NEU2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 51/734 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs760542299, COSV52092700; called by muse, mutect2
- NF1 | c.7262A>C p.N2421T (on ENST00000358273 / NM_001042492.3; = p.N2400T on NM_000267.3) | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs774339063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPBL | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV99240920; called by muse, mutect2, varscan2
- NLRP7 | c.2343C>A p.F781L (on ENST00000340844 / NM_206828.3; = p.F753L on NM_139176.3) | Missense Mutation (SNP) | VAF 32/848 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60170647, COSV60176575; called by muse, mutect2
- NOD2 | c.2217C>A p.F739L | Missense Mutation (SNP) | VAF 47/845 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56048398; called by muse, mutect2
- NOTCH1 | c.7234C>A p.P2412T | Missense Mutation (SNP) | VAF 239/1151 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV53052947; called by muse, mutect2, varscan2
- NPHP3 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV58129721; called by muse, mutect2, varscan2
- NSD2 | c.924T>G p.I308M | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as rs760909823; called by muse, mutect2, varscan2
- NSUN6 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as rs774577958, COSV66031702; called by muse, mutect2, varscan2
- NUMA1 | c.3283G>T p.A1095S | Missense Mutation (SNP) | VAF 157/645 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as rs1290384268; called by muse, mutect2, varscan2
- NYAP1 | c.1359dup p.K454Qfs*112 | Frame Shift Ins (INS) | VAF 79/514 reads (15%) | catalogued as rs1355570169; called by mutect2, varscan2
- OBSCN | c.15157G>A p.E5053K | Missense Mutation (SNP) | VAF 130/558 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772564832; called by muse, varscan2
- OCRL | c.601A>G p.K201E | Missense Mutation (SNP) | VAF 56/638 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV63981432; called by muse, mutect2
- OLFM1 | c.1240G>A p.V414I (on ENST00000371793 / NM_001282611.2; = p.V396I on NM_014279.5) | Missense Mutation (SNP) | VAF 63/737 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as rs766525119, COSV53277115; called by muse, mutect2
- OR10A6 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs549286517, COSV100564294; called by muse, mutect2
- OR10G4 | c.760T>C p.C254R | Missense Mutation (SNP) | VAF 105/470 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV57977941; called by muse, varscan2
- OR10J1 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 74/345 reads (21%) | catalogued as COSV71128713; called by muse, varscan2
- OR11G2 | c.721A>C p.S241R | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs913277800; called by muse, mutect2
- OR11H6 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs760092591, COSV59644056; called by muse, mutect2, varscan2
- OR2M5 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs749940471, COSV63545804, COSV63546155, COSV99057361; called by muse, mutect2, varscan2
- OR2T10 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 71/378 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV100393712; called by muse, mutect2, varscan2
- OR2T6 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 93/524 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs771583152; called by muse, mutect2, varscan2
- OR2Z1 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV60692502; called by muse, mutect2, varscan2
- OR5AN1 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs1177245319; called by muse, mutect2, varscan2
- OR5D16 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 96/526 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs375832312, COSV65722636; called by muse, mutect2, varscan2
- OR5K1 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60304375, COSV60304635; called by muse, mutect2, varscan2
- OR5K1 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as COSV60303853; called by muse, mutect2, varscan2
- OSBP2 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 143/718 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100212880; called by muse, mutect2, varscan2
- OTOG | c.3703A>C p.T1235P | Missense Mutation (SNP) | VAF 90/448 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs764534477; called by muse, mutect2, varscan2
- P2RY10 | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 141/588 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50680618; called by muse, mutect2, varscan2
- P4HB | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751445347; called by muse, mutect2, varscan2
- PAK5 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 60/397 reads (15%) | catalogued as COSV62031633; called by muse, mutect2, varscan2
- PANK1 | c.960C>A p.F320L (on ENST00000307534 / NM_148977.2; = p.F95L on NM_138316.4) | Missense Mutation (SNP) | VAF 43/501 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56808154; called by muse, mutect2
- PANX2 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 222/990 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50304550; called by muse, mutect2, varscan2
- PARK7 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as CM144904; called by muse, mutect2, varscan2
- PARP11 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 14/200 reads (7%) | catalogued as rs1396248877, COSV99959025; called by muse, mutect2
- PATJ | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57155927; called by muse, mutect2, varscan2
- PCBP4 | c.1071C>A p.F357L (on ENST00000322099 / NM_033010.2; = p.F314L on NM_020418.4) | Missense Mutation (SNP) | VAF 168/816 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100436878; called by muse, mutect2, varscan2
- PCDHA11 | c.2375C>A p.S792* | Nonsense Mutation (SNP) | VAF 23/513 reads (4%) | catalogued as COSV100251269; called by muse, mutect2
- PCDHB15 | c.1903G>C p.V635L | Missense Mutation (SNP) | VAF 239/1030 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV50999990; called by muse, mutect2, varscan2
- PCDHGA9 | c.1217C>A p.T406K | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53916555; called by muse, mutect2, varscan2
- PCDHGB2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1160500738; called by muse, mutect2, varscan2
- PCLO | c.10642G>T p.E3548* | Nonsense Mutation (SNP) | VAF 42/419 reads (10%) | catalogued as COSV61629087; called by muse, mutect2
- PDE11A | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 69/235 reads (29%) | catalogued as rs780484841, COSV53687032; called by muse, mutect2, varscan2
- PDS5B | c.905C>A p.A302E | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100221223; called by muse, mutect2, varscan2
- PEG10 | c.947C>A p.S316* (on ENST00000482108 / NM_001040152.2; = p.S350* on NM_015068.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 57/599 reads (10%) | catalogued as COSV99072291; called by muse, mutect2
- PER3 | c.1670G>T p.R557I | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62704786, COSV62707891; called by muse, mutect2, varscan2
- PEX13 | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV54371727; called by muse, mutect2, varscan2
- PHYHD1 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs201188576; called by muse, mutect2, varscan2
- PIBF1 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454565631, COSV58327467; called by muse, mutect2, varscan2
- PIK3R1 | c.1465G>T p.E489* (on ENST00000521381 / NM_181523.3; = p.E219* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 48/133 reads (36%) | catalogued as CM136437, COSV57128610; called by muse, mutect2, varscan2
- PIP | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs1255901035, COSV52120152, COSV52120798; called by muse, mutect2, varscan2
- PKD1L3 | c.4499G>T p.R1500I | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1009872899; called by mutect2, varscan2
- PLAG1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as COSV57614746; called by muse, mutect2, varscan2
- PLCH2 | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as rs1200846027; called by muse, mutect2
- PLEKHG4B | c.3349G>T p.E1117* (on ENST00000283426; = p.E1473* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 76/335 reads (23%) | catalogued as COSV99361543; called by muse, mutect2, varscan2
- PMS2 | c.1753C>A p.L585I | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as rs63750947, COSV56220451, COSV99763837; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- POLE | c.5609G>A p.R1870H | Missense Mutation (SNP) | VAF 78/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758619238, COSV100268743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1B | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV54497003; called by muse, mutect2
- POU3F4 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 140/654 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100937351, COSV64539271; called by muse, mutect2, varscan2
- PPFIA2 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 35/385 reads (9%) | catalogued as COSV100333776, COSV61052166; called by muse, mutect2
- PPIB | c.271A>G p.S91G | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs368454186; called by muse, mutect2, varscan2
- PPP1R3C | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as rs769285267; called by muse, mutect2, varscan2
- PRAMEF2 | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs529323357, COSV53577332; called by muse, mutect2, varscan2
- PRKAA1 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 28/357 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV57183256, COSV57185517; called by muse, mutect2
- PRKD2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 68/397 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1459489245; called by muse, mutect2, varscan2
- PRKDC | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1490137907; called by muse, mutect2
- PRR30 | c.351G>T p.W117C | Missense Mutation (SNP) | VAF 120/585 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1452295363; called by muse, mutect2, varscan2
- PSMA1 | c.188T>A p.I63N | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs781276795; called by muse, mutect2, varscan2
- PTPN23 | c.2034C>A p.F678L | Missense Mutation (SNP) | VAF 145/683 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs551844731; called by muse, mutect2, varscan2
- PTPRB | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54245447; called by muse, mutect2, varscan2
- QRICH1 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 97/445 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV62614643; called by muse, mutect2, varscan2
- RAD23B | c.677T>G p.L226* | Nonsense Mutation (SNP) | VAF 21/181 reads (12%) | catalogued as COSV100787680; called by muse, mutect2, varscan2
- RAG1 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 107/503 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); catalogued as rs1279281327, COSV55024702; called by muse, mutect2, varscan2
- RB1 | c.2712G>T p.M904I | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.074); catalogued as rs1461167778, COSV57297074, COSV57328407; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RB1CC1 | c.2006G>T p.R669I | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV50252872; called by muse, mutect2
- RELN | c.5137G>A p.E1713K | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV100632538; called by muse, mutect2
- RHOH | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 132/662 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67806466; called by muse, mutect2, varscan2
- RNF111 | c.698T>G p.L233* | Nonsense Mutation (SNP) | VAF 36/136 reads (26%) | catalogued as COSV62085532; called by muse, mutect2, varscan2
- RNF220 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 22/560 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100132014; called by muse, mutect2
- RNPEPL1 | c.1988C>G p.P663R | Missense Mutation (SNP) | VAF 58/920 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs747342765; called by muse, mutect2
- RP1 | c.4130A>G p.D1377G | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as rs1332588522; called by muse, mutect2, varscan2
- RPAP2 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 28/177 reads (16%) | catalogued as COSV72509310; called by muse, mutect2, varscan2
- RPH3A | c.916C>A p.P306T (on ENST00000389385 / NM_001143854.2; = p.P302T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/504 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101231829; called by muse, mutect2, varscan2
- RPUSD2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 94/421 reads (22%) | catalogued as COSV59765287; called by muse, varscan2
- RTN1 | c.694A>C p.K232Q | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99956824; called by muse, mutect2, varscan2
- RXRA | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs779808577; called by muse, mutect2, varscan2
- SACS | c.7408G>T p.D2470Y | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66533535; called by muse, mutect2, varscan2
- SALL2 | c.2909C>A p.A970D | Missense Mutation (SNP) | VAF 124/581 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as rs368220424, COSV58101844; called by muse, mutect2, varscan2
- SAP30BP | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1276395021; called by muse, mutect2, varscan2
- SBNO1 | c.916G>T p.E306* (on ENST00000420886; = p.E305* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 52/212 reads (25%) | catalogued as COSV57342611; called by muse, mutect2, varscan2
- SCN1A | c.1493G>T p.R498I | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1448731908; called by muse, mutect2, varscan2
- SCTR | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 95/504 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs149693113; called by muse, mutect2, varscan2
- SEC23A | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56976702; called by muse, mutect2, varscan2
- SEMA3D | c.2274G>T p.K758N | Missense Mutation (SNP) | VAF 73/453 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV52391816, COSV52392691; called by muse, mutect2, varscan2
- SERINC3 | c.1009A>C p.N337H | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54855791; called by muse, mutect2, varscan2
- SETD1A | c.3613C>T p.R1205W | Missense Mutation (SNP) | VAF 187/875 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs775350343, COSV99353939; called by muse, mutect2, varscan2
- SETDB1 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV104376595; called by muse, mutect2
- SF3B2 | c.508C>A p.H170N | Missense Mutation (SNP) | VAF 64/420 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100488533; called by muse, mutect2, varscan2
- SFPQ | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 91/393 reads (23%) | catalogued as COSV100599510, COSV61758332; called by muse, mutect2, varscan2
- SGK1 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52816001; called by muse, mutect2, varscan2
- SGK1 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52804532; called by mutect2, varscan2
- SGK3 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV61897148; called by muse, mutect2, varscan2
- SH3KBP1 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 75/385 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as COSV65640986; called by muse, mutect2, varscan2
- SH3RF1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs755358542; called by muse, mutect2, varscan2
- SIDT2 | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 71/482 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54056037, COSV54058632; called by muse, mutect2, varscan2
- SLC10A6 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 53/312 reads (17%) | catalogued as COSV99907295; called by muse, mutect2, varscan2
- SLC12A2 | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52472062; called by muse, mutect2
- SLC16A6 | c.1176T>G p.F392L | Missense Mutation (SNP) | VAF 70/392 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs782733542; called by muse, mutect2, varscan2
- SLC22A18 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 24/649 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1270035771; called by muse, mutect2
- SLC24A1 | c.1551C>A p.F517L | Missense Mutation (SNP) | VAF 99/418 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56053059, COSV56053894; called by muse, varscan2
- SLC27A6 | c.1515C>A p.F505L | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV99323568; called by muse, mutect2, varscan2
- SLC35F4 | c.691T>A p.F231I (on ENST00000339762 / NM_001352015.2; = p.F195I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs1329993734; called by muse, varscan2
- SLC4A9 | c.409G>T p.A137S (on ENST00000507527 / NM_001258428.2; = p.A113S on NM_031467.3) | Missense Mutation (SNP) | VAF 126/615 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.119); catalogued as rs756451645; called by muse, mutect2, varscan2
- SLC6A16 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 134/579 reads (23%) | catalogued as COSV60030520; called by muse, mutect2, varscan2
- SLC6A3 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 46/811 reads (6%) | catalogued as COSV54362925; called by muse, mutect2
- SLC8A1 | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV60491946; called by muse, mutect2, varscan2
- SLC8A3 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 88/427 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs766322163, COSV63526605; called by muse, mutect2, varscan2
- SLITRK3 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 42/546 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs367841040; called by muse, mutect2
- SLITRK3 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 87/414 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV53845266, COSV53846493; called by muse, mutect2, varscan2
- SMG7 | c.1788G>T p.K596N | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.289); catalogued as COSV61630700; called by muse, mutect2, varscan2
- SNCB | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 72/397 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs779230513, COSV59435914; called by muse, mutect2, varscan2
- SNX1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 91/353 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1426456011; called by muse, mutect2, varscan2
- SORBS3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 114/529 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs146179804; called by muse, mutect2, varscan2
- SOX11 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 101/580 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100431061; called by muse, mutect2, varscan2
- SPTBN1 | c.4505G>T p.G1502V | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV100441981; called by muse, mutect2
- SRRM4 | c.1791C>A p.S597R | Missense Mutation (SNP) | VAF 122/883 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99937760; called by muse, mutect2, varscan2
- STAB2 | c.6744G>T p.W2248C | Missense Mutation (SNP) | VAF 106/462 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004434876; called by muse, mutect2, varscan2
- STARD9 | c.8846G>T p.R2949I | Missense Mutation (SNP) | VAF 95/417 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1363358955; called by muse, mutect2, varscan2
- STEAP4 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 71/391 reads (18%) | catalogued as COSV57331145; called by muse, mutect2, varscan2
- STRN | c.2243G>T p.R748L | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55747537; called by muse, mutect2
- STYXL2 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 35/563 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54802974, COSV54807351; called by muse, mutect2
- SVBP | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1557600735, COSV65301273; called by muse, mutect2
- SYCP2 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV62770266; called by muse, mutect2, varscan2
- SYMPK | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 110/585 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1347777046; called by muse, mutect2, varscan2
- SYNE2 | c.17149A>G p.T5717A | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs754627479; called by muse, mutect2
- SYNE3 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 130/608 reads (21%) | catalogued as COSV62082777; called by muse, mutect2, varscan2
- SYNM | c.4645G>T p.A1549S (on ENST00000336292 / NM_145728.3; = p.A1237S on NM_015286.6) | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782156525; called by muse, mutect2, varscan2
- SYT4 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54898241, COSV99674071; called by muse, mutect2, varscan2
- TAOK3 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1328458063, COSV66825383; called by muse, mutect2, varscan2
- TBC1D14 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV68987436; called by muse, mutect2
- TENM3 | c.5208G>T p.M1736I | Missense Mutation (SNP) | VAF 23/611 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101305208; called by muse, mutect2
- TES | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV64043045; called by muse, mutect2
- TEX47 | c.85A>G p.N29D | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1211714115; called by muse, mutect2, varscan2
- TGS1 | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs765414360; called by mutect2, varscan2
- TIMP3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 139/640 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs200592407; called by muse, mutect2, varscan2
- TKT | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 119/579 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs782390818; called by muse, mutect2, varscan2
- TLK1 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 65/391 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1335662117; called by muse, mutect2, varscan2
- TLN2 | c.6259G>T p.D2087Y | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1057460564; called by muse, mutect2, varscan2
- TRAF4 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 130/621 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52218010; called by muse, mutect2, varscan2
- TREM1 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.586); catalogued as rs772655224, COSV55148210, COSV55148868; called by muse, mutect2, varscan2
- TRIM71 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 124/597 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.051); catalogued as rs1310080218; called by muse, mutect2, varscan2
- TRPM5 | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 32/570 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as rs1184515027, COSV50144870; called by muse, mutect2
- TSHZ1 | c.1478C>A p.S493Y (on ENST00000580243 / NM_001308210.2; = p.S448Y on NM_005786.6) | Missense Mutation (SNP) | VAF 112/537 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV59010139; called by muse, mutect2, varscan2
- TTN | c.98305G>T p.E32769* (on ENST00000591111; = p.E25345* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 45/296 reads (15%) | catalogued as COSV60168668; called by muse, mutect2, varscan2
- TTN | c.40807G>T p.E13603* (on ENST00000591111; = p.E6179* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 43/236 reads (18%) | catalogued as COSV60134666; called by muse, mutect2, varscan2
- TTN | c.32313G>T p.K10771N (on ENST00000591111; = p.K9844N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/107 reads (24%) | PolyPhen benign (0.322); catalogued as COSV100614515; called by muse, mutect2, varscan2
- UBLCP1 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs1448101670, COSV57142644; called by muse, mutect2, varscan2
- UBR5 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 25/417 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55302677; called by muse, mutect2
- UPK1B | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.253); catalogued as COSV51767162; called by muse, mutect2, varscan2
- URGCP | c.948G>T p.W316C (on ENST00000453200 / NM_001077663.3; = p.W307C on NM_017920.4) | Missense Mutation (SNP) | VAF 95/426 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs768644545, COSV56245878; called by muse, mutect2, varscan2
- USH1C | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 30/632 reads (5%) | catalogued as COSV50039605; called by muse, mutect2
- USP51 | c.1122G>T p.M374I | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1427903383, COSV72351621; called by muse, mutect2, varscan2
- USPL1 | c.2703G>T p.K901N | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV54999805, COSV55001029; called by muse, mutect2, varscan2
- VNN1 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100907751; called by mutect2, varscan2
- VWA8 | c.5618G>T p.R1873I | Missense Mutation (SNP) | VAF 35/384 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV65001555; called by muse, mutect2
- WDCP | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 101/485 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV54592943; called by muse, mutect2, varscan2
- WDFY4 | c.2782C>A p.L928I | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1435753287; called by muse, mutect2, varscan2
- WDR35 | c.631C>A p.H211N | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV55605138; called by muse, mutect2
- WFDC1 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV54745733; called by muse, mutect2, varscan2
- YEATS4 | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 38/698 reads (5%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as COSV56088496; called by muse, mutect2
- YTHDF3 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV72773399; called by muse, mutect2, varscan2
- ZBTB11 | c.2325C>A p.F775L | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758124325, COSV100465510, COSV57246578; called by muse, mutect2, varscan2
- ZC3H12B | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 33/493 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100161556, COSV100161973; called by muse, mutect2
- ZFP42 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV58817465; called by muse, mutect2
- ZKSCAN7 | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56272188; called by muse, mutect2, varscan2
- ZNF214 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV53483439; called by muse, mutect2, varscan2
- ZNF226 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 17/140 reads (12%) | catalogued as rs1399159138; called by muse, mutect2, varscan2
- ZNF229 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 101/520 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs759283205; called by muse, mutect2, varscan2
- ZNF256 | c.913A>C p.N305H | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV56597054; called by muse, mutect2
- ZNF404 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs1167607351, COSV60988924; called by muse, mutect2, varscan2
- ZNF419 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as rs763862940; called by muse, mutect2, varscan2
- ZNF430 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55110576; called by muse, mutect2, varscan2
- ZNF461 | c.1466G>T p.R489I | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs1235527164, COSV64455331; called by muse, mutect2, varscan2
- ZNF461 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 59/254 reads (23%) | catalogued as COSV100831535; called by muse, mutect2, varscan2
- ZNF48 | c.1856G>T p.*619Lext*19 | Nonstop Mutation (SNP) | VAF 22/285 reads (8%) | catalogued as COSV100198238; called by muse, mutect2
- ZNF560 | c.1743C>A p.F581L | Missense Mutation (SNP) | VAF 19/350 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100038927; called by muse, mutect2
- ZNF626 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1555769549; called by muse, mutect2
- ZNF630 | c.332C>A p.S111* | Nonsense Mutation (SNP) | VAF 41/196 reads (21%) | catalogued as COSV52095852; called by muse, mutect2, varscan2
- ZNF667 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as rs1287171553, COSV52631050, COSV52637836; called by muse, mutect2, varscan2
- ZNF730 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV101659646, COSV74168366; called by muse, mutect2, varscan2
- ZNF850 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 39/204 reads (19%) | catalogued as rs1223213187; called by muse, mutect2, varscan2
- ZNF91 | c.2504T>G p.F835C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104394847; called by muse, mutect2, varscan2
- ZNF98 | c.689G>T p.R230I | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV63334241; called by muse, varscan2
- AAMP | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 78/403 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AARS2 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 166/971 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ABCA12 | c.3435C>A p.F1145L (on ENST00000272895 / NM_173076.3; = p.F827L on NM_015657.3) | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.345); called by muse, mutect2
- ABCA7 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 107/547 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2
- ABCF1 | c.852C>A p.F284L (on ENST00000326195 / NM_001025091.2; = p.F246L on NM_001090.3) | Missense Mutation (SNP) | VAF 130/591 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABHD13 | c.606G>T p.L202F | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ABI1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 114/623 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC092718.8 | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- ACADS | c.213G>T p.V71= | Splice Region (SNP) | VAF 90/479 reads (19%) | called by muse, mutect2, varscan2
- ACHE | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 99/753 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACOX1 | c.1593C>A p.C531* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | called by mutect2, varscan2
- ACP3 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 62/628 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACSM5 | c.899T>A p.V300D | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, varscan2
- ACTL8 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 179/801 reads (22%) | called by muse, mutect2, varscan2
- ACVR1 | c.241T>C p.C81R | Missense Mutation (SNP) | VAF 133/576 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR1B | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADAM18 | c.627A>C p.Q209H | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2
- ADAMDEC1 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADARB1 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 38/690 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2
- ADCY10 | c.3157A>C p.I1053L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY8 | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 108/488 reads (22%) | called by muse, mutect2, varscan2
- ADNP2 | c.2795C>A p.A932D | Missense Mutation (SNP) | VAF 51/548 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2
- AFF1 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 76/372 reads (20%) | called by muse, mutect2, varscan2
- AFF3 | c.2543C>A p.S848Y | Missense Mutation (SNP) | VAF 37/466 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); called by muse, mutect2
- AGAP5 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- AIDA | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, varscan2
- AIDA | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 48/228 reads (21%) | called by muse, varscan2
- AIM2 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 80/387 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.5158G>T p.E1720* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- AKR1D1 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- AMER1 | c.970T>G p.S324A | Missense Mutation (SNP) | VAF 138/712 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANK3 | c.10833G>T p.M3611I | Missense Mutation (SNP) | VAF 89/423 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ANK3 | c.5210C>A p.A1737D | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKIB1 | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 68/416 reads (16%) | called by muse, mutect2, varscan2
- ANKRD10 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 22/602 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2
- ANKRD11 | c.3653A>C p.K1218T | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- ANKRD20A1 | c.2030A>C p.K677T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- ANKRD31 | c.4971dup p.S1658Ifs*10 | Frame Shift Ins (INS) | VAF 45/232 reads (19%) | called by mutect2, pindel, varscan2
- ANKRD40 | c.1068G>T p.R356S | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ANKRD42 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ANTXRL | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); called by muse, mutect2
- AP1S2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APBA2 | c.1589C>A p.A530D | Missense Mutation (SNP) | VAF 153/762 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- APC | c.3272dup p.H1092Tfs*27 | Frame Shift Ins (INS) | VAF 59/323 reads (18%) | called by mutect2, pindel, varscan2
- APC | c.6938C>A p.A2313D | Missense Mutation (SNP) | VAF 83/502 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- APC2 | c.5251C>A p.P1751T | Missense Mutation (SNP) | VAF 50/944 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- APOB | c.5881A>C p.S1961R | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ARFGAP3 | c.1526C>A p.S509* | Nonsense Mutation (SNP) | VAF 42/270 reads (16%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.5357A>C p.*1786Sext*28 | Nonstop Mutation (SNP) | VAF 13/296 reads (4%) | called by muse, mutect2
- ARHGAP11A | c.301A>C p.K101Q | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ARHGAP12 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- ARHGAP15 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP15 | c.1288T>G p.L430V | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2
- ARHGAP32 | c.1657T>C p.S553P (on ENST00000310343 / NM_001378025.1; = p.S204P on NM_014715.4) | Missense Mutation (SNP) | VAF 92/451 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGAP5 | c.2000C>A p.S667* | Nonsense Mutation (SNP) | VAF 42/264 reads (16%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.1976T>C p.L659P | Missense Mutation (SNP) | VAF 40/641 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF18 | c.644A>G p.Q215R (on ENST00000359920 / NM_001130955.2; = p.Q111R on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGEF6 | c.2205G>T p.M735I | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- ARID2 | c.3485C>A p.T1162N | Missense Mutation (SNP) | VAF 80/437 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ARID3C | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 166/753 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ARID4B | c.2308G>A p.V770I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMCX2 | c.1498A>C p.N500H | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARMCX2 | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ART1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 58/800 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.091); called by muse, mutect2
- ASCC3 | c.5141A>C p.K1714T | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASXL3 | c.5033G>A p.G1678D | Missense Mutation (SNP) | VAF 98/437 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ATF7IP | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, varscan2
- ATIC | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ATP10B | c.3944T>G p.F1315C | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ATP13A1 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP1A4 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V1F | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 63/346 reads (18%) | called by muse, mutect2, varscan2
- ATP7A | c.2141T>A p.L714* | Nonsense Mutation (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- ATP8B4 | c.3156T>G p.F1052L | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRNL1 | c.2876G>T p.G959V | Missense Mutation (SNP) | VAF 67/383 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN3L | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 74/398 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by mutect2, varscan2
- AZI2 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- B2M | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 55/254 reads (22%) | called by muse, mutect2, varscan2
- BANK1 | c.397A>C p.S133R | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, varscan2
- BBOX1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- BCL9 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 35/701 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BCL9 | c.3246G>T p.M1082I | Missense Mutation (SNP) | VAF 135/647 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCLAF1 | c.2571T>G p.D857E | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- BEND4 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- BEX4 | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4918A>C p.T1640P | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- BLK | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 70/350 reads (20%) | called by muse, mutect2, varscan2
- BOD1L1 | c.3648G>T p.M1216I | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- BRD1 | c.1567A>C p.K523Q | Missense Mutation (SNP) | VAF 82/535 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRD1 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 119/536 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BRSK1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 103/502 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BTBD7 | c.214A>C p.K72Q | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2
- BTBD8 | c.3260C>T p.T1087I (on ENST00000636805 / NM_001376131.1; = p.T574I on NM_015237.4) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BUD31 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 21/317 reads (7%) | called by muse, mutect2
- C11orf65 | c.684G>T p.W228C | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C13orf42 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- C16orf89 | c.592T>A p.S198T | Missense Mutation (SNP) | VAF 122/533 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C17orf80 | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- C1D | c.189A>C p.L63F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- C1QTNF8 | c.102G>C p.W34C | Missense Mutation (SNP) | VAF 184/943 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- C5AR1 | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CABS1 | c.958A>G p.R320G | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CACNA1H | c.5438T>A p.I1813N | Missense Mutation (SNP) | VAF 39/489 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1S | c.3008C>A p.A1003D | Missense Mutation (SNP) | VAF 99/602 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CAD | c.3932C>A p.P1311H | Missense Mutation (SNP) | VAF 19/525 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CADM1 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALCOCO1 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP1 | c.2938G>T p.A980S | Missense Mutation (SNP) | VAF 94/462 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CAPS2 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.03); called by mutect2, varscan2
- CARD11 | c.2552A>G p.H851R | Missense Mutation (SNP) | VAF 62/1024 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- CARMIL1 | c.3082G>T p.E1028* | Nonsense Mutation (SNP) | VAF 15/235 reads (6%) | called by muse, mutect2
- CASP8 | c.331G>T p.E111* (on ENST00000432109 / NM_033355.3; = p.E143* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- CATSPERE | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- CBFA2T2 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 118/700 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2
- CC2D1B | c.2210A>G p.Q737R | Missense Mutation (SNP) | VAF 54/534 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2
- CCDC141 | c.2157C>A p.F719L | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC157 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 132/667 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CCDC168 | c.3524A>G p.E1175G | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2
- CCDC175 | c.1871T>G p.L624* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- CCDC177 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 143/811 reads (18%) | called by muse, mutect2, varscan2
- CCDC82 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC88A | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- CCDC88C | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CD163L1 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 30/356 reads (8%) | called by muse, mutect2
- CD2 | c.1034C>A p.S345* | Nonsense Mutation (SNP) | VAF 110/441 reads (25%) | called by muse, mutect2, varscan2
- CDC25A | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH13 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDS2 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR2 | c.3589C>A p.P1197T | Missense Mutation (SNP) | VAF 85/781 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CELSR2 | c.5488A>C p.N1830H | Missense Mutation (SNP) | VAF 100/476 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CENPE | c.5446G>A p.A1816T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CENPF | c.6452C>A p.S2151* | Nonsense Mutation (SNP) | VAF 18/378 reads (5%) | called by muse, mutect2
- CEP162 | c.3693G>T p.E1231D | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CES4A | c.1474A>C p.S492R (on ENST00000648724 / NM_001364782.1; = p.S394R on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/640 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- CFAP43 | c.4465G>T p.E1489* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | called by mutect2, varscan2
- CFAP47 | c.2576G>C p.R859T | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- CFAP70 | c.377C>A p.P126Q | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CFAP97D1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 89/443 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFL1 | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 29/468 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by muse, mutect2
- CHCHD4 | c.58C>A p.H20N (on ENST00000396914 / NM_001098502.2; = p.H33N on NM_144636.3) | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CHD2 | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 98/508 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- CHD3 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHD4 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 88/425 reads (21%) | called by muse, mutect2, varscan2
- CHD6 | c.5458G>T p.E1820* | Nonsense Mutation (SNP) | VAF 22/460 reads (5%) | called by muse, mutect2
- CHI3L2 | c.12del p.T5Pfs*11 | Frame Shift Del (DEL) | VAF 73/378 reads (19%) | called by mutect2, pindel, varscan2
- CIITA | c.3182C>A p.A1061D | Missense Mutation (SNP) | VAF 52/666 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CKM | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 116/648 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CLASP2 | c.3767C>T p.A1256V (on ENST00000359576; = p.A1255V on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CLEC4F | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 97/527 reads (18%) | called by muse, mutect2, varscan2
- CLN8 | c.86T>A p.V29D | Missense Mutation (SNP) | VAF 35/911 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- CLRN3 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CMBL | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMIP | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 154/685 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CNOT1 | c.6978C>A p.F2326L | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNST | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- CNTNAP4 | c.187A>T p.R63* | Nonsense Mutation (SNP) | VAF 78/315 reads (25%) | called by muse, mutect2, varscan2
- COL11A2 | c.2959C>A p.P987T (on ENST00000341947 / NM_080680.3; = p.P880T on NM_080679.2) | Missense Mutation (SNP) | VAF 128/612 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by mutect2, varscan2
- COL4A5 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 96/601 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- COLQ | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 49/411 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COPS4 | c.603C>A p.F201L | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COQ9 | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 56/704 reads (8%) | called by muse, mutect2
- CPLANE1 | c.*1829+1G>T | Splice Site (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- CPSF2 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- CPT1A | c.2065A>T p.T689S | Missense Mutation (SNP) | VAF 21/497 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CRAMP1 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 182/839 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CREM | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- CRIPT | c.245T>G p.I82S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CRISP3 | c.609T>G p.C203W (on ENST00000371159 / NM_001368123.1; = p.C185W on NM_006061.4) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRISPLD2 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 126/638 reads (20%) | called by muse, mutect2
- CRLF2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 106/478 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CRYBG2 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 107/464 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSDE1 | c.516T>A p.S172R (on ENST00000358528 / NM_001007553.3; = p.S141R on NM_007158.6) | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, varscan2
- CSMD1 | c.2111C>A p.P704H (on ENST00000520002; = p.P703H on NM_033225.6) | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.1507A>C p.S503R (on ENST00000297405 / NM_001363185.1; = p.S399R on NM_052900.3) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK2A1 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTR9 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2
- CTR9 | c.1935G>T p.K645N | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CUZD1 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CXorf38 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 45/319 reads (14%) | called by muse, mutect2, varscan2
- CXorf66 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2U1 | c.214T>G p.F72V | Missense Mutation (SNP) | VAF 191/876 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DACT3 | c.486G>C p.R162S | Missense Mutation (SNP) | VAF 66/921 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DBF4B | c.656G>T p.R219I | Missense Mutation (SNP) | VAF 63/398 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DCAF1 | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 33/427 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); called by muse, mutect2
- DCAF12L2 | c.606G>T p.W202C | Missense Mutation (SNP) | VAF 190/798 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDIAS | c.929A>T p.K310M | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DDX39B | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 66/591 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DDX53 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2
- DHX37 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); called by muse, mutect2
- DISP1 | c.2504G>T p.R835I | Missense Mutation (SNP) | VAF 96/456 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DLG5 | c.4963T>G p.Y1655D | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by mutect2, varscan2
- DLX3 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 105/457 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- DNAH1 | c.11196C>A p.C3732* | Nonsense Mutation (SNP) | VAF 126/612 reads (21%) | called by muse, varscan2
- DNAH12 | c.1445A>T p.N482I | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DNAH17 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 70/379 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DNAH7 | c.4249G>T p.E1417* | Nonsense Mutation (SNP) | VAF 37/239 reads (15%) | called by muse, mutect2, varscan2
- DNAH8 | c.1605C>A p.F535L | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- DNAJB6 | c.312T>G p.F104L | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC10 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.338); called by muse, mutect2
- DNM2 | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 100/528 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, varscan2
- DNMT1 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 79/378 reads (21%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK10 | c.3643A>G p.N1215D | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DOCK2 | c.4018C>A p.P1340T | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK8 | c.1830T>G p.F610L | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- DOK3 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 62/924 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- DOP1A | c.7386G>T p.M2462I | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); called by mutect2, varscan2
- DOT1L | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 54/576 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPY19L3 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPYD | c.1189A>C p.I397L | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAM | c.5727T>G p.F1909L | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DSEL | c.2942G>T p.R981I | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- DSP | c.1447A>T p.I483F | Missense Mutation (SNP) | VAF 87/451 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DSPP | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, varscan2
- DUSP7 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DYNC1H1 | c.9341A>G p.D3114G | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2
- DYNC1I2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 76/390 reads (19%) | called by muse, mutect2, varscan2
- DYRK1A | c.1987A>T p.T663S | Missense Mutation (SNP) | VAF 104/494 reads (21%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYRK4 | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 53/704 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- E2F7 | c.2445G>T p.Q815H | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); called by muse, mutect2
- EDC3 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 91/458 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EFCAB12 | c.1694C>A p.A565D | Missense Mutation (SNP) | VAF 89/406 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- EFCC1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 138/735 reads (19%) | called by muse, mutect2, varscan2
- EFL1 | c.2593T>G p.L865V | Missense Mutation (SNP) | VAF 75/414 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EIF4A2 | c.751T>G p.Y251D | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF5B | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ELF3 | c.653del p.D218Afs*36 | Frame Shift Del (DEL) | VAF 79/412 reads (19%) | called by mutect2, pindel, varscan2
- ELOVL3 | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 93/534 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ELP1 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ELP3 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 53/334 reads (16%) | called by muse, mutect2, varscan2
- ELP5 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 75/370 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMC1 | c.1691T>G p.V564G | Missense Mutation (SNP) | VAF 109/485 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ENOX2 | c.775T>A p.L259I (on ENST00000338144 / NM_001382520.1; = p.L230I on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHA7 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 93/433 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- EPHB1 | c.2404A>T p.T802S | Missense Mutation (SNP) | VAF 20/643 reads (3%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.966); called by muse, mutect2
- ERAS | c.212A>C p.D71A | Missense Mutation (SNP) | VAF 142/796 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ERBIN | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- ERICH2 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 68/295 reads (23%) | called by muse, mutect2, varscan2
- ESCO2 | c.1619T>G p.V540G | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ETNK2 | c.798C>A p.F266L | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- EVPLL | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EYA4 | c.754T>G p.Y252D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- F10 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 113/640 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- F5 | c.4983A>C p.K1661N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- F8 | c.6256C>A p.P2086T | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2
- FAM111B | c.1965T>G p.F655L | Missense Mutation (SNP) | VAF 87/354 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FAM171A1 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FAM205A | c.2735A>G p.K912R | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FAM227B | c.527T>G p.L176* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- FAM234B | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 89/523 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- FAM83H | c.1266C>A p.N422K | Missense Mutation (SNP) | VAF 113/975 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- FAM9A | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 126/807 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.82); called by mutect2, varscan2
- FANCA | c.3298C>A p.P1100T | Missense Mutation (SNP) | VAF 36/804 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.386); called by muse, mutect2
- FAP | c.2226C>A p.N742K | Missense Mutation (SNP) | VAF 92/390 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.2932G>T p.D978Y | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.8029A>C p.I2677L | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FBXO38 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- FCF1 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FHDC1 | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FHOD1 | c.2073G>T p.M691I | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.246); called by muse, mutect2
- FIBIN | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 53/665 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- FILIP1L | c.3379A>T p.T1127S (on ENST00000354552 / NM_182909.3; = p.T887S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- FNDC3A | c.2931G>T p.K977N (on ENST00000492622 / NM_001079673.2; = p.K921N on NM_014923.5) | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FOCAD | c.3761A>G p.K1254R | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FOXA2 | c.611A>G p.Q204R (on ENST00000377115 / NM_153675.3; = p.Q210R on NM_021784.5) | Missense Mutation (SNP) | VAF 51/570 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- FSIP2 | c.8382G>T p.M2794I | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- FUBP1 | c.1836T>A p.S612R | Missense Mutation (SNP) | VAF 106/522 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FUBP3 | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- GAB3 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 28/750 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- GALR1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 69/910 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.331); called by muse, mutect2
- GARRE1 | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 103/517 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GFM1 | c.1768T>G p.F590V | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- GIPC3 | c.1818G>T p.K606N | Missense Mutation (SNP) | VAF 91/483 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- GLRX3 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 25/501 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- GOLGA8K | c.1748C>A p.A583D | Missense Mutation (SNP) | VAF 118/474 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GPAT3 | c.708A>C p.L236F | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, varscan2
- GPR107 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2
- GPR34 | c.467T>A p.I156N | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPRASP2 | c.1504C>A p.L502I | Missense Mutation (SNP) | VAF 46/652 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.067); called by muse, mutect2
- GPSM1 | c.1755C>A p.H585Q | Missense Mutation (SNP) | VAF 38/984 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.389); called by muse, mutect2
- GRK4 | c.196C>A p.L66I (on ENST00000398052 / NM_182982.3; = p.L34I on NM_005307.3) | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GSG1L2 | c.50T>A p.L17H | Missense Mutation (SNP) | VAF 120/646 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GUCY2C | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- GUF1 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- GYS1 | c.1248G>T p.M416I | Missense Mutation (SNP) | VAF 64/350 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- H3-3B | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 34/545 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- HAT1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- HECTD1 | c.6757G>T p.A2253S | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- HERC2 | c.5705G>T p.G1902V | Missense Mutation (SNP) | VAF 61/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HHIP | c.1689C>A p.Y563* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- HIP1R | c.2249C>A p.A750D | Missense Mutation (SNP) | VAF 185/892 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HKDC1 | c.1668C>A p.N556K | Missense Mutation (SNP) | VAF 67/444 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, varscan2
- HLTF | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMGB3 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.845dup p.Y283Lfs*6 (on ENST00000354667 / NM_031243.3; = p.Y271Lfs*6 on NM_002137.4) | Frame Shift Ins (INS) | VAF 70/388 reads (18%) | called by mutect2, pindel, varscan2
- HNRNPCL2 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 49/636 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- HNRNPUL1 | c.1313C>A p.A438D | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOOK3 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- HOXA11 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- HOXB3 | c.553T>A p.S185T | Missense Mutation (SNP) | VAF 28/776 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.161); called by muse, mutect2
- HPD | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 41/497 reads (8%) | called by muse, mutect2
- HS6ST2 | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 136/642 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HS6ST2 | c.1039T>G p.S347A | Missense Mutation (SNP) | VAF 134/643 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- HSD17B13 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HUWE1 | c.6719C>A p.A2240D | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- IFIT2 | c.887T>G p.F296C | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- IFT172 | c.1563G>T p.M521I | Missense Mutation (SNP) | VAF 84/379 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGF2BP3 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 58/682 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2
- IGKV1D-42 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL1R1 | c.223C>A p.H75N | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- IL27RA | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 108/519 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INAFM2 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 32/796 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- ING5 | c.412dup p.R138Kfs*26 | Frame Shift Ins (INS) | VAF 69/325 reads (21%) | called by mutect2, pindel, varscan2
- INTS6L | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- INTS7 | c.2581A>G p.K861E | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- IPO13 | c.1266T>G p.I422M | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- IQCA1L | c.1400A>C p.K467T | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- IQCH | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IQSEC1 | c.446A>C p.Q149P | Missense Mutation (SNP) | VAF 31/720 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- IRS4 | c.2470G>T p.D824Y | Missense Mutation (SNP) | VAF 107/517 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- IRS4 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 157/837 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ITGA11 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 139/556 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA9 | c.641C>A p.S214* | Nonsense Mutation (SNP) | VAF 28/338 reads (8%) | called by muse, mutect2
- ITGAV | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- ITGAV | c.2792C>A p.S931* | Nonsense Mutation (SNP) | VAF 49/230 reads (21%) | called by muse, mutect2, varscan2
699 further variants in this file (427 protein-altering or splice-affecting, 216 silent, 56 other) are not listed here.
